Gene-level copy-number profile of tumor specimen TCGA-HF-7136-01A from TCGA case TCGA-HF-7136, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2.
Specimen TCGA-HF-7136-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a77f72bb-6149-4104-9213-9f2221bdbbb5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HF-7136-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f68917d8-a4ad-4935-bbc1-7736296f2071

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 2,644; copy number 2: 16,881; copy number 3: 24,463; copy number 4: 10,999; copy number 5: 3,875; copy number 6: 757; copy number 7: 58; copy number 8: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HF-7136-01A-11D-2052-01): tumor purity 0.75, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,250,687–3,627,296, 1 gene (within-gene range 0–3): AC034195.1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:177,120,691–177,126,120, 2 genes: Y_RNA, RNU6-681P.
- chr4:151,333,775–151,408,835, 2 genes: AC104819.3, FAM160A1-DT.
- chr5:100,375,700–105,392,970, 40 genes (within-gene range 0–2): AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P.
- chr18:51,028,394–51,159,383, 2 genes (within-gene range 0–2): SMAD4, SRSF10P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 144 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–55,542,054, 140 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:22,169,589–22,228,029, 4 genes, copy number 8: GATA6, RNU6-702P, AC091588.3, AC091588.2.

Autosomal genes at a single copy (total copy number 1): 263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
